Surgical pathology report (de-identified scan), TCGA case TCGA-F5-6861, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Asterand, specimen TCGA-F5-6861-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

[Redacted]

Formatted Path Report

[Redacted]	[Redacted]	[Redacted]		
------------	------------	------------	--	--

[page 2 of 3]
	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Anterior resection of rectum Specimen size: Not specified Tumor site: Rectum Tumor size: 6 x 6 x 1.5 cm Tumor features: Exophytic (polypoid) Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Perirectal tissues Lymph nodes: 0/8 positive for metastasis (Regional 0/8) Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
--	---

Source: NCI Genomic Data Commons file 337aa361-7ca1-40a6-bb05-9139b8cede43 (TCGA-F5-6861.599D4BD5-2464-4BB5-97DB-C5E65DE78755.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).